CCDI case PBCHZK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/04a73d09-28bd-4e2c-bcd7-3a1215ace6a1

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ossifying fibromyxoid tumor: ICD-O-3 morphology code: 8842/0; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.0 years (4,029 days).

Biospecimens (3 samples)
- Samples 0DSBXZ, 0DSBYI (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSBY9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
